TCGA case TCGA-DD-A1EH — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cab5b264-abab-4bdb-816e-9d2c0ac30629

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 23 years; Vital status: Alive.

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 23.3 years (8,499 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: B; Ishak fibrosis score: 3,4 - Fibrous Septa.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Macro.
   Treatment given: Treatment type: Ablation, Radiofrequency; Days to treatment start: 126 days; Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib; Days to treatment start: 358 days; Days to treatment end: 863 days (2.4 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Days to treatment start: 553 days (1.5 years); Days to treatment end: 721 days (2.0 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Everolimus + Gemcitabine; Days to treatment start: 862 days (2.4 years); Days to treatment end: 975 days (2.7 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 23.6 years (8,619 days); Days to diagnosis: 120 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 23.6 years (8,619 days); Days to diagnosis: 120 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 120 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 120 days.
- Day 120 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 120 days.
- Days to follow up: 1,036 days (2.8 years); Disease response: With Tumor.
- Days to follow up: 1,495 days (4.1 years); Disease response: With Tumor.
- ECOG performance status: 1.

Molecular and laboratory tests
- Total Bilirubin 1 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Alpha Fetoprotein 94340 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Prothrombin Time 10.4 Seconds [Blood test normal range lower: 9.5; Blood test normal range upper: 13.8].
- Platelets 212 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Albumin 4.7 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Creatinine 1 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.3].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 179 cm; BMI: 21.8.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV Surface Antibody / HBV Core Antibody / HBV DNA.

Family history
- Relatives with cancer history count: 1.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A1EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-DD-A1EH-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A1EH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A1EH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-DD-A1EH-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-DD-A1EH-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 75; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy; Ishak fibrosis score: 3,4 - Fibrous Speta.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Surface Antibody; Viral hepatitis serology: HBV Core Antibody; Viral hepatitis serology: Hbv dna.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 3: Pharmaceutical therapy drug name: Everolimus, Gemcitabine, and Cisplatin; Treatment best response: Clinical Progressive Disease.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: Yes.
- Ablations, Ablation, Ablation treatments, Ablation treatment: Ablation type: Radiofrequency Ablation; Treatment cycles count: 1.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,495 days; disease-specific survival: no event (censored), 1,495 days; disease-free interval: event (new tumor event after initially disease-free), 120 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 120 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-A1EH-01A-11D-A12Y-01): tumor purity 0.87, ploidy 1.99, whole-genome doublings 0.
